Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4332, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4332-01A (Primary Tumor).

[page 1 of 2]
....

Clinical Diagnosis & History:

[REDACTED] with left upper pole renal mass.

Specimens Submitted:

- 1: SP: Lt. renal tumor [REDACTED]
2: SP: Deep margin #2, lt. kidney [REDACTED]
3: SP: Portion of left eleventh rib [REDACTED]

DIAGNOSIS:

- 1) KIDNEY, LEFT; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL AND CLEAR CELL TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR GREATEST DIAMETER IS 4.0 CM.
- THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- 2) KIDNEY, LEFT DEEP MARGIN #2; BIOPSY:
- BENIGN RENAL TISSUE.
- 3) RIB, PORTION OF LEFT ELEVENTH; EXCISION:
- GROSSLY UNREMARKABLE. SECTIONS NOT YET READY BECAUSE OF NEED TO DECALCIFY. IF SIGNIFICANT ABNORMALITIES ARE FOUND, AN ADDENDUM REPORT WILL BE ISSUED.
- [REDACTED]
- [REDACTED]

Gross Description:

- 1) The specimen is received fresh for frozen section, labeled "Left Renal Tumor". It consists of a partial nephrectomy specimen measuring 5 x 5 x 4 cm. The deep margin is inked in black, the capsule is inked in blue, and the specimen is serially sectioned. The cut surface reveals a fairly well-circumscribed, partially encapsulated tumor measuring 4 x 4 x 3.5 cm. The cut surface of the tumor is yellow and multicystic. The cysts are variable in size. There are some areas of fibrosis and hemorrhage within the tumor. The tumor appears to be at 0.3 cm from the inked deep margin of resection. The tumor appears also to be bulging into the perirenal fat, but not invading into it. Representative sections are submitted.

Summary of Sections:

FSC - frozen section control
TM - tumor to deep margin
TC - tumor to capsule

[REDACTED]

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

2) The specimen is received fresh for frozen section, labeled "Deep Margin #2". It consists of one fragment of tan soft tissue measuring 0.4 x 0.2 x 0.2 cm. Entirely frozen.

Summary of Sections:

FSC - frozen section control

3) The specimen is received in formalin, labeled "Portion of left 11th rib". It consists of a hemorrhagic pink-tan segment of rib with attached fibromuscular tissue, measuring 9.2 cm in length by 1.2 cm in maximal diameter, entirely sectioned to reveal a hard, pink-tan cut surface. Representative sections are submitted.

Summary of Sections:

T -- Tips

U -- Undesignated cross-cuts

Summary of Sections:

Part 1: SP: Lt. renal tumor

Block	Sect. Site	PCs
1	FSC	1
3	TC	3
4	TM	4

Part 2: SP: Deep margin #2, Lt. kidney

Block	Sect. Site	PCs
1	FSC	1

Part 3: SP: Portion of left eleventh rib

Block	Sect. Site	PCs
1	t	2
1	u	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM; MARGIN IS NEGATIVE.
PERMANENT DIAGNOSIS: SAME.

2) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file ba99df93-52ac-4c87-a457-f42ca7e1c487 (TCGA-BP-4332.D05BCA89-84E4-488B-847F-3A67C1BDB82B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).